Somatic mutation profile of tumor specimen C3N-01714-02 (aliquot CPT0124360006_1) from CPTAC case C3N-01714, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,163 days).
Specimen C3N-01714-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17a33498-0d26-457c-986b-e3b6b20cb8e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01714-31 (Blood Derived Normal), aliquot CPT0124390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8183574-cead-4bde-8a21-ef88291af445

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 5'Flank 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/572 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 71/689 reads (10%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABRAXAS2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs968863430, COSV53716833; called by muse, mutect2
- ADCK5 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 36/904 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1206845562; called by muse, mutect2
- ADGRB3 | c.1445G>C p.C482S | Missense Mutation (SNP) | VAF 44/610 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101002291; called by muse, mutect2
- ASTL | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); catalogued as rs373382016; called by muse, mutect2
- BMP7 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 74/824 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs371762840; called by muse, mutect2
- BNC2 | c.1509G>T p.R503S | Missense Mutation (SNP) | VAF 42/881 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV66149783; called by muse, mutect2
- CFAP54 | c.6232C>T p.R2078C | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as rs375947114; called by muse, mutect2
- DCLK1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs373217123; called by muse, mutect2
- EVX2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs765774536, COSV57963877; called by muse, mutect2
- GRAMD1B | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs1247803361; called by muse, mutect2
- LCE3D | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 86/1040 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs749727744, COSV100909887; called by muse, mutect2
- PCDHA11 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 52/1118 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100247543; called by muse, mutect2
- PCED1B | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs375607179; called by muse, mutect2
- PLXNB2 | c.3845A>G p.D1282G | Missense Mutation (SNP) | VAF 105/1077 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833925; called by muse, mutect2
- POU3F2 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60408656, COSV60409574; called by muse, mutect2
- RPS6KA3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs980055137; called by muse, mutect2, varscan2
- SGK2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 35/494 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs149168513; called by muse, mutect2
- TMEM132D | c.2188G>T p.D730Y | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV67159692; called by muse, mutect2
- CDC42BPB | c.2526G>A p.M842I | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- CNTLN | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2
- DCAF8L2 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); called by muse, mutect2
- DYNC2I1 | c.1526A>C p.D509A | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2
- ERN2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2
- FAM107A | c.327+5G>T | Splice Region (SNP) | VAF 41/943 reads (4%) | called by muse, mutect2
- GALNT7 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 23/212 reads (11%) | called by mutect2, varscan2
- HHLA1 | c.590-1G>T p.X197_splice | Splice Site (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- KALRN | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF5C | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLB | c.1473A>T p.K491N | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.258); called by muse, mutect2
- PCDHA8 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 98/1578 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2
- PROSER2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SMG1 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- SPICE1 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- SYNM | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 62/824 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.085); called by muse, mutect2
- TMEM215 | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2
- TRPS1 | c.222C>G p.D74E (on ENST00000220888 / NM_001330599.2; = p.D87E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/833 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.301); called by muse, mutect2
- WDR5B | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 40/664 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- ZNF831 | c.3951A>C p.R1317S | Missense Mutation (SNP) | VAF 22/625 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- CYP26B1 | c.345C>T p.T115= | Silent (SNP) | VAF 12/357 reads (3%) | catalogued as COSV50011727; called by muse, mutect2
- DNAH9 | c.9729G>A p.P3243= | Silent (SNP) | VAF 43/765 reads (6%) | catalogued as rs149731222; called by muse, mutect2
- IRX1 | c.624C>T p.S208= | Silent (SNP) | VAF 37/714 reads (5%) | catalogued as COSV100116237, COSV57361038; called by muse, mutect2
- KIF21B | c.1497C>T p.N499= | Silent (SNP) | VAF 32/468 reads (7%) | catalogued as rs1422871934; called by muse, mutect2
- LMBRD2 | c.1299C>T p.I433= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs187816551, COSV56950263; called by muse, mutect2, varscan2
- LPA | c.2736G>A p.A912= | Silent (SNP) | VAF 51/1597 reads (3%) | catalogued as rs1344439639; called by muse, mutect2
- PCDHA13 | c.1302G>A p.S434= | Silent (SNP) | VAF 45/1044 reads (4%) | catalogued as COSV56496912; called by muse, mutect2
- RAB11FIP2 | c.444C>T p.T148= | Silent (SNP) | VAF 18/256 reads (7%) | catalogued as rs188765663, COSV62924859; called by muse, mutect2
- TENM2 | c.2145G>A p.T715= (on ENST00000518659 / NM_001122679.2; = p.T483= on NM_001080428.3) | Silent (SNP) | VAF 26/635 reads (4%) | catalogued as rs1333891430, COSV69140727; called by muse, mutect2
- TTN | c.34761T>C p.S11587= (on ENST00000591111; = p.S10660= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/476 reads (7%) | catalogued as rs773883685; ClinVar: likely benign; called by muse, mutect2
- CCDC33 | c.2139+58C>T | Intron (SNP) | VAF 45/359 reads (13%) | catalogued as rs528890370; called by muse, mutect2, varscan2
- ERGIC3 | chr20:35559187 G>A | 3'Flank (SNP) | VAF 31/326 reads (10%) | catalogued as rs937707491; called by muse, mutect2
- YAF2 | chr12:42238627 G>T | 5'Flank (SNP) | VAF 29/332 reads (9%) | catalogued as rs1048682127; called by muse, mutect2
